Somatic mutation profile of tumor specimen TCGA-50-5931-01A (aliquot TCGA-50-5931-01A-11D-1753-08) from TCGA case TCGA-50-5931, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.9 years (27,733 days).
Specimen TCGA-50-5931-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80a79cd5-e342-434d-b996-464c32f6efac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5931-11A (Solid Tissue Normal), aliquot TCGA-50-5931-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ebd754b-e02d-4b3e-b5bf-adb55191ccfc

The open-access MAF lists 332 somatic variants for this specimen: 254 protein-altering or splice-affecting, 71 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 219, Silent 71, Nonsense Mutation 18, Splice Site 6, Frame Shift Del 6, Intron 4, Frame Shift Ins 2, 5'Flank 1, RNA 1, Nonstop Mutation 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 40/51 reads (78%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3616G>T p.A1206S | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV70042299; called by muse, mutect2, varscan2
- AHSG | c.781C>G p.P261A | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV56609153; called by muse, mutect2, varscan2
- AKAP3 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1345037350, COSV57420026; called by muse, mutect2
- AKR1B15 | c.814dup p.T272Nfs*29 | Frame Shift Ins (INS) | VAF 22/44 reads (50%) | catalogued as rs768391747; called by mutect2, varscan2
- ANK2 | c.10322G>A p.R3441Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); catalogued as rs772954896, COSV52148056; ClinVar: likely benign; called by muse, mutect2, varscan2
- APBB1IP | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV63304209; called by muse, mutect2, varscan2
- ARID2 | c.865A>G p.I289V | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57613279; called by muse, mutect2, varscan2
- ARMC12 | c.566G>T p.R189L (on ENST00000373866 / NM_001286574.2; = p.R216L on NM_145028.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as COSV55359551; called by muse, mutect2, varscan2
- ARMC3 | c.1446G>T p.L482F | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53066642; called by muse, mutect2, varscan2
- ARRDC5 | c.452A>G p.Y151C (on ENST00000381781; = p.Y137C on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.25); PolyPhen benign (0.072); catalogued as rs762771067, COSV67788257; called by muse, mutect2, varscan2
- ASH1L | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); catalogued as COSV64212988; called by muse, mutect2, varscan2
- ASTL | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV60905260; called by muse, mutect2, varscan2
- ATP11C | c.866+2T>C p.X289_splice | Splice Site (SNP) | VAF 25/102 reads (25%) | catalogued as COSV59572769; called by muse, mutect2, varscan2
- ATP2C1 | c.2915G>T p.C972F (on ENST00000507488 / NM_001378511.1; = p.C948F on NM_001001486.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as COSV53910245; called by muse, mutect2, varscan2
- B3GNT8 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs769992042, COSV99524337, COSV99524519; called by muse, mutect2, varscan2
- BCORL1 | c.1818G>C p.Q606H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV54405541; called by muse, mutect2, varscan2
- BEND2 | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.091); catalogued as COSV101192226, COSV66217067; called by muse, mutect2, varscan2
- BMT2 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs1472806191, COSV51780477; called by muse, mutect2, varscan2
- BRD4 | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54593812; called by muse, mutect2, varscan2
- BTN1A1 | c.1291G>T p.G431* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV55069420; called by muse, mutect2, varscan2
- BVES | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58949737; called by muse, mutect2, varscan2
- C6 | c.2756G>T p.C919F | Missense Mutation (SNP) | VAF 125/197 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54717214; called by muse, mutect2, varscan2
- CAMTA1 | c.2609T>A p.V870E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV57923351; called by muse, mutect2, varscan2
- CATSPER3 | c.1051A>T p.I351F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV50949397; called by muse, mutect2, varscan2
- CCDC14 | c.1343G>C p.S448T (on ENST00000488653; = p.S400T on NM_022757.5) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100112803; called by muse, mutect2, varscan2
- CCSER2 | c.722C>A p.S241* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV56511391; called by muse, mutect2, varscan2
- CD48 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 76/230 reads (33%) | catalogued as COSV100924183, COSV63567610; called by muse, mutect2, varscan2
- CDH18 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 128/195 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56930417; called by muse, mutect2, varscan2
- CDH8 | c.1883T>A p.L628* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV54895681; called by muse, mutect2, varscan2
- CDH9 | c.229-1G>T p.X77_splice | Splice Site (SNP) | VAF 36/154 reads (23%) | catalogued as COSV50291441; called by muse, mutect2, varscan2
- CHM | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63304106; called by muse, mutect2, varscan2
- CHRDL1 | c.1131G>T p.K377N (on ENST00000372045; = p.K383N on NM_145234.4) | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54323758, COSV54328409, COSV99488737; called by muse, mutect2, varscan2
- CHST10 | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV51807435; called by muse, mutect2, varscan2
- CLCA4 | c.1502C>A p.A501D | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs555270545, COSV55370735; called by muse, mutect2, varscan2
- COL11A1 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.377); catalogued as rs761765612, COSV100615367, COSV62195294; called by muse, mutect2, varscan2
- COL14A1 | c.2606C>G p.P869R | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as COSV52866289; called by muse, mutect2, varscan2
- COL19A1 | c.3419G>A p.G1140D | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV59586178; called by muse, mutect2, varscan2
- COL1A2 | c.3881G>C p.G1294A | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51961766, COSV51964959; called by muse, mutect2, varscan2
- COL21A1 | c.2460C>A p.C820* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV55177771; called by muse, mutect2, varscan2
- COL9A3 | c.1420C>A p.L474M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.952); catalogued as COSV58986989; called by muse, mutect2, varscan2
- CRACD | c.1975C>A p.P659T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.121); catalogued as COSV51730367; called by muse, mutect2, varscan2
- CRB1 | c.2921C>G p.T974S | Missense Mutation (SNP) | VAF 93/148 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs575358595, COSV66328981, COSV66333082; called by muse, mutect2, varscan2
- CRYBG3 | c.7182C>A p.F2394L | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV51715590; called by muse, mutect2, varscan2
- CSMD1 | c.7451G>T p.W2484L (on ENST00000520002; = p.W2483L on NM_033225.6) | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59375332; called by muse, mutect2, varscan2
- CSMD2 | c.1250C>G p.T417S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV53955300; called by muse, mutect2, varscan2
- CXCL6 | c.271T>G p.C91G | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56903396; called by muse, mutect2, varscan2
- CYP3A43 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV55937736; called by muse, mutect2, varscan2
- DCAF12L2 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.033); catalogued as COSV100758816, COSV63583978; called by muse, mutect2, varscan2
- DIP2A | c.2677G>T p.A893S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1569094068, COSV100594931; called by muse, mutect2, varscan2
- DMBT1 | c.3148C>A p.Q1050K (on ENST00000338354 / NM_001377530.1; = p.Q551K on NM_004406.3) | Missense Mutation (SNP) | VAF 120/132 reads (91%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV57559042; called by muse, mutect2, varscan2
- DNAAF1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV54742019; called by muse, mutect2, varscan2
- DNMT3A | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as COSV53074779; called by muse, mutect2, varscan2
- DST | c.8974G>A p.V2992I | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99748996; called by muse, mutect2, varscan2
- DST | c.6561A>G p.I2187M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV99749003; called by muse, mutect2, varscan2
- ETV1 | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV54150288; called by muse, mutect2, varscan2
- EYA4 | c.1900C>A p.L634M (on ENST00000531901 / NM_001301013.1; = p.L628M on NM_004100.5) | Missense Mutation (SNP) | VAF 116/221 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as COSV62059723; called by muse, mutect2, varscan2
- F8 | c.4975C>A p.P1659T | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.299); catalogued as COSV64277983; called by muse, mutect2, varscan2
- F9 | c.724-1G>T p.X242_splice | Splice Site (SNP) | VAF 60/133 reads (45%) | catalogued as CS083921, CS910433, CS941482, COSV54380044; called by muse, mutect2, varscan2
- FAM177B | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV62601759; called by muse, mutect2, varscan2
- FAM193A | c.1385A>C p.H462P | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); catalogued as COSV61198155; called by muse, mutect2, varscan2
- FANCB | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV60761499; called by muse, mutect2, varscan2
- FCRL3 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 99/159 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV63844549; called by muse, mutect2, varscan2
- FIG4 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57790986; called by muse, mutect2, varscan2
- FLNA | c.5344G>C p.G1782R (on ENST00000369850 / NM_001110556.2; = p.G1774R on NM_001456.3) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV61050323; called by muse, mutect2, varscan2
- FLT4 | c.2305G>T p.E769* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV56120295, COSV99988619; called by muse, mutect2, varscan2
- FOLH1 | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV57055746; called by muse, mutect2, varscan2
- FOXD1 | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100197577; called by muse, mutect2
- FOXO4 | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV58576310; called by muse, mutect2, varscan2
- FRMPD1 | c.3407C>T p.S1136F | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV66702742; called by muse, mutect2, varscan2
- GABBR1 | c.609G>T p.R203S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63544296; called by muse, mutect2, varscan2
- GABRR2 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101298769; called by muse, varscan2
- GALNT6 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62541984, COSV62543246; called by muse, mutect2, varscan2
- GAP43 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV59347868; called by muse, mutect2, varscan2
- GCKR | c.671C>A p.S224* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs987416895, COSV53110780, COSV53111004; called by muse, mutect2
- GCKR | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.612); catalogued as COSV53110787; called by muse, mutect2
- GEMIN5 | c.4262G>T p.C1421F | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as COSV53564313; called by muse, mutect2, varscan2
- GLIS1 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56551516, COSV56555273; called by muse, mutect2, varscan2
- GLUD2 | c.890C>A p.P297Q | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV60152933; called by muse, mutect2, varscan2
- GNAT1 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV50032037; called by muse, mutect2, varscan2
- GPLD1 | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.482); catalogued as rs1228915497, COSV57760598; called by muse, mutect2, varscan2
- GPR174 | c.174G>C p.M58I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99337870, COSV99338336; called by muse, mutect2, varscan2
- GRIN2A | c.4181A>T p.Q1394L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV58054531; called by muse, mutect2, varscan2
- GRIN2C | c.1316A>T p.H439L | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53117412; called by muse, mutect2, varscan2
- GRM4 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs745359442, COSV100946639, COSV65218945; called by muse, mutect2, varscan2
- GRM5 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59603919, COSV59625716; called by muse, mutect2, varscan2
- GSPT2 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV61215018; called by muse, mutect2, varscan2
- GUCA1B | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV57835229, COSV57835857; called by muse, mutect2
- HAPLN1 | c.907C>A p.R303S | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs773075190, COSV99164500; called by muse, mutect2, varscan2
- HAPLN1 | c.906C>A p.D302E | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99164501; called by muse, mutect2, varscan2
- HEPH | c.1453C>A p.H485N (on ENST00000343002; = p.H218N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57970970; called by muse, mutect2, varscan2
- HEPHL1 | c.2690A>G p.Y897C | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs776065811, COSV59895814; called by muse, mutect2, varscan2
- HK3 | c.1504G>T p.A502S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV99457480; called by muse, mutect2, varscan2
- HK3 | c.1503G>T p.Q501H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV99457490; called by muse, mutect2, varscan2
- HOXB9 | c.534C>G p.N178K | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV60817721; called by muse, mutect2, varscan2
- IFNGR2 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs945274699, COSV51640915; called by muse, mutect2, varscan2
- IGSF3 | c.2863G>T p.V955L (on ENST00000369486 / NM_001007237.3; = p.V975L on NM_001542.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV59597742; called by muse, mutect2, varscan2
- IL18RAP | c.984G>C p.Q328H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV51823896, COSV51828812; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1862A>G p.Q621R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs371810135, COSV56295107, COSV56307243; called by muse, mutect2, varscan2
- IRX2 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.558); catalogued as COSV57413371; called by muse, mutect2, varscan2
- KCNB1 | c.2168C>A p.S723Y | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.445); catalogued as COSV65570552; called by muse, mutect2, varscan2
- KDF1 | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57672030; called by muse, mutect2, varscan2
- KIF20A | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV50165966; called by muse, mutect2
- KIF4A | c.2493T>A p.S831R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV65545477; called by muse, mutect2, varscan2
- KIF5A | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54058538; called by muse, mutect2, varscan2
- KIRREL2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV52879728; called by muse, mutect2, varscan2
- KLHL26 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56319416; called by muse, mutect2, varscan2
- KLHL9 | c.1525T>C p.Y509H | Missense Mutation (SNP) | VAF 179/216 reads (83%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV100756962; called by muse, mutect2, varscan2
- KMT2D | c.2002G>T p.E668* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV56438771, COSV56438888; called by muse, mutect2, varscan2
- KMT2D | c.2001G>T p.E667D | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.098); catalogued as COSV99976192; called by muse, mutect2, varscan2
- KRT2 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200999971, COSV59012475; called by muse, mutect2, varscan2
- LAMA4 | c.504-1G>T p.X168_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV57891971, COSV57903937; called by muse, mutect2, varscan2
- LARS1 | c.1846C>T p.H616Y (on ENST00000394434 / NM_020117.11; = p.H589Y on NM_016460.3) | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0.028); catalogued as COSV50986767; called by muse, mutect2, varscan2
- LEPR | c.464A>T p.Y155F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.111); catalogued as COSV60763215; called by muse, mutect2, varscan2
- LRATD2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100513498; called by muse, varscan2
- MCF2 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as COSV58481077; called by muse, mutect2, varscan2
- MEDAG | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV66850838; called by muse, mutect2, varscan2
- MEIS1 | c.870G>C p.W290C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55491694; called by muse, mutect2, varscan2
- MGA | c.3197G>T p.R1066L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54961825; called by muse, mutect2, varscan2
- MICAL2 | c.2423G>A p.R808K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV56325622; called by muse, mutect2, varscan2
- MSH2 | c.1066A>G p.I356V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV51884208; called by muse, mutect2, varscan2
- MSTN | c.343A>T p.T115S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV99640431; called by muse, mutect2, varscan2
- MTHFD1L | c.1234G>T p.G412* | Nonsense Mutation (SNP) | VAF 50/101 reads (50%) | catalogued as COSV66210283; called by muse, mutect2, varscan2
- MTMR8 | c.1794G>A p.M598I | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV66396001; called by muse, mutect2, varscan2
- MUC16 | c.23966C>G p.T7989R | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV67480737, COSV67489321; called by muse, mutect2, varscan2
- MUC16 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as COSV67489330; called by muse, mutect2, varscan2
- MUC17 | c.1036G>T p.V346F | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as COSV60301231; called by muse, mutect2, varscan2
- MYBPC1 | c.865G>T p.G289C (on ENST00000550270 / NM_206820.2; = p.G314C on NM_002465.4) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62257083; called by muse, mutect2, varscan2
- MYH2 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55447180; called by muse, mutect2, varscan2
- MYH4 | c.5500C>A p.Q1834K | Missense Mutation (SNP) | VAF 62/76 reads (82%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV55124997; called by muse, mutect2, varscan2
- MYO1A | c.3081G>T p.K1027N | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV55657055; called by muse, mutect2, varscan2
- NAGA | c.1208T>C p.I403T | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs995869251, COSV67170270; called by muse, mutect2, varscan2
- NBEA | c.7177G>A p.E2393K | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV59817937; called by muse, mutect2, varscan2
- NDUFS3 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as COSV55456173; called by muse, mutect2
- NETO1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs140307788; called by muse, mutect2, varscan2
- NLGN1 | c.766A>T p.T256S | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64345075; called by muse, mutect2, varscan2
- NMUR1 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.924); catalogued as rs1189327099, COSV59403800, COSV59405586; called by muse, mutect2, varscan2
- NOTCH1 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV53087953; called by muse, mutect2, varscan2
- NPAP1 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV61506192, COSV61510653; called by muse, mutect2, varscan2
- NPAS4 | c.1514C>T p.T505I | Missense Mutation (SNP) | VAF 113/208 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as rs200495885, COSV60652571; called by muse, mutect2, varscan2
- NPR1 | c.2285C>A p.P762H | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.618); catalogued as COSV64118066, COSV64118274; called by muse, mutect2, varscan2
- NRG3 | c.1004C>G p.T335S | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV64581168; called by muse, mutect2, varscan2
- NRK | c.2651T>A p.V884E | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs771113520, COSV54605328; called by muse, mutect2, varscan2
- NTM | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66186374, COSV66188318; called by muse, mutect2, varscan2
- OR10K2 | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV59222564; called by muse, mutect2, varscan2
- OR12D2 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV65830026; called by muse, mutect2
- OR14C36 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.513); catalogued as COSV58602630; called by muse, mutect2, varscan2
- OR1J4 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.17); catalogued as COSV61589788, COSV61590245; called by muse, mutect2, varscan2
- OR2L2 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 107/382 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs375068162; called by muse, mutect2, varscan2
- OR2V2 | c.25T>A p.Y9N | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV60316348; called by muse, mutect2, varscan2
- OR51T1 | c.982T>A p.*328Rext*? | Nonstop Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100434231; called by muse, mutect2, varscan2
- OR5AS1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as COSV57983063; called by muse, mutect2, varscan2
- OR6K2 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV62743337, COSV62744145; called by muse, mutect2, varscan2
- OR8J3 | c.635T>A p.I212N | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV56883825; called by muse, mutect2, varscan2
- P2RY10 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50685080; called by muse, mutect2, varscan2
- PARP8 | c.282A>T p.R94S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV55866092; called by mutect2, varscan2
- PARVA | c.517A>G p.R173G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1163578533, COSV58517806; called by muse, mutect2, varscan2
- PCBP3 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV68409810; called by muse, mutect2, varscan2
- PCDHA12 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs571648883, COSV56475315; called by muse, mutect2, varscan2
- PCDHB2 | c.1257C>A p.Y419* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99164060; called by muse, mutect2, varscan2
- PCDHB3 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.029); catalogued as COSV50563981, COSV50623980; called by muse, mutect2, varscan2
- PCDHB8 | c.1385G>C p.R462P | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.087); catalogued as rs782085896, COSV50754200, COSV50809082; called by muse, mutect2, varscan2
- PCDHGA5 | c.982G>T p.V328F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV54019036; called by muse, mutect2, varscan2
- PCLO | c.15393G>C p.W5131C | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61615407, COSV61661533; called by muse, mutect2, varscan2
- PDE4B | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 81/165 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as COSV58492986; called by muse, mutect2, varscan2
- PDHA2 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54778510, COSV54778966; called by muse, mutect2, varscan2
- PIKFYVE | c.2008A>T p.I670F | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52248257; called by muse, mutect2, varscan2
- PIP4K2C | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772477787, COSV61606920; called by muse, mutect2, varscan2
- PLG | c.422C>A p.T141K | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51986042; called by muse, mutect2, varscan2
- POLQ | c.3229C>G p.L1077V | Missense Mutation (SNP) | VAF 136/203 reads (67%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV51760081; called by muse, mutect2, varscan2
- PPEF1 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV62996527; called by muse, mutect2, varscan2
- PPFIA2 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV61035926; called by muse, mutect2, varscan2
- PPP2R2D | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101409008; called by muse, mutect2, varscan2
- PRICKLE3 | c.900C>A p.C300* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV66234500, COSV66235482; called by muse, mutect2, varscan2
- PTH1R | c.1339T>C p.F447L | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV57317566; called by muse, mutect2, varscan2
- PTPRCAP | c.584C>A p.A195E | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100396131; called by muse, mutect2, varscan2
- PYDC2 | c.134C>G p.T45R | Missense Mutation (SNP) | VAF 73/118 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV101573343, COSV72921503; called by muse, varscan2
- RAI2 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100518088; called by muse, mutect2, varscan2
- RASGRF2 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as COSV54137499; called by muse, mutect2, varscan2
- RASGRP4 | c.1030G>C p.A344P | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as COSV53097701; called by muse, mutect2
- REG3G | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV55451371, COSV55452005; called by muse, mutect2, varscan2
- RICTOR | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV57129474; called by muse, mutect2, varscan2
- RIMS1 | c.4565G>T p.G1522V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53477093, COSV53480238; called by muse, mutect2, varscan2
- RPE65 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV52018338; called by muse, mutect2, varscan2
- RYR2 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 20/26 reads (77%) | catalogued as COSV63710095; called by muse, mutect2, varscan2
- RYR2 | c.12519A>G p.I4173M | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1553322892, COSV63710113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV66806335; called by muse, mutect2, varscan2
- RYR3 | c.12004G>A p.E4002K (on ENST00000389232; = p.E4003K on NM_001036.6) | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66806338; called by muse, mutect2, varscan2
- SACS | c.2905A>T p.S969C | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV66546099; called by muse, mutect2, varscan2
- SDCCAG8 | c.1736A>G p.D579G | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100653644; called by muse, mutect2
- SEC62 | c.943A>C p.S315R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV61262156; called by muse, mutect2, varscan2
- SERPINI2 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 87/141 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs1248667681, COSV52986011; called by muse, mutect2, varscan2
- SF3B4 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.376); catalogued as COSV54966757; called by muse, mutect2, varscan2
- SFPQ | c.1939G>T p.G647C | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61759221; called by muse, mutect2, varscan2
- SIGLEC5 | c.1620C>A p.S540R | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs551417438, COSV55783348; called by muse, mutect2, varscan2
- SIM1 | c.1770C>G p.D590E | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs375025782; called by muse, mutect2, varscan2
- SLC13A5 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs554762818, COSV53424925; called by muse, mutect2, varscan2
- SLC2A13 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55126907; called by muse, mutect2, varscan2
- SLC30A10 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 71/117 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV63074953; called by muse, mutect2, varscan2
- SLC6A8 | c.985A>T p.S329C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53473325; called by muse, mutect2, varscan2
- SLC9A6 | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV65788910; called by muse, mutect2, varscan2
- SLC9A9 | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs917844916, COSV57242998; called by muse, mutect2, varscan2
- SLC9C2 | c.3002C>G p.T1001S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV62948886; called by muse, varscan2
- SP7 | c.977G>C p.C326S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58191970; called by muse, mutect2, varscan2
- SPAG9 | c.1900G>A p.A634T (on ENST00000262013 / NM_001130528.3; = p.A620T on NM_003971.6) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as rs750278227, COSV56239956; called by muse, mutect2, varscan2
- SPTBN2 | c.6501G>T p.P2167= | Splice Region (SNP) | VAF 36/79 reads (46%) | catalogued as COSV59450987, COSV59460362; called by muse, mutect2, varscan2
- SSTR1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99942605; called by muse, mutect2, varscan2
- SYT4 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV54903738; called by muse, mutect2, varscan2
- TBC1D19 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 47/99 reads (47%) | catalogued as rs141345574; called by muse, mutect2, varscan2
- TDO2 | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs759094500, COSV72483911, COSV72483933; called by muse, mutect2, varscan2
- TEX14 | c.730G>T p.A244S (on ENST00000240361 / NM_001201457.2; = p.A238S on NM_031272.5) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV53617962, COSV53625034, COSV99543805; called by muse, mutect2, varscan2
- TMEM185A | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 135/368 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57560492; called by muse, mutect2, varscan2
- TRHDE | c.1627C>A p.H543N | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV53863051; called by muse, mutect2, varscan2
- TRIP12 | c.1681-1G>T p.X561_splice | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as COSV52271804; called by muse, mutect2, varscan2
- TRO | c.192C>A p.N64K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV51506960; called by muse, mutect2, varscan2
- TSHZ2 | c.1358G>T p.C453F | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as COSV61591110; called by muse, mutect2, varscan2
- TTN | c.94300G>A p.A31434T (on ENST00000591111; = p.A24010T on NM_003319.4) | Missense Mutation (SNP) | VAF 62/115 reads (54%) | PolyPhen probably damaging (0.998); catalogued as COSV60301476; called by muse, mutect2, varscan2
- TTN | c.68327C>A p.P22776Q (on ENST00000591111; = p.P15352Q on NM_003319.4) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | PolyPhen possibly damaging (0.837); catalogued as COSV100587685; called by muse, mutect2, varscan2
- TTN | c.68326C>A p.P22776T (on ENST00000591111; = p.P15352T on NM_003319.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | PolyPhen benign (0.344); catalogued as COSV100587689; called by muse, mutect2, varscan2
- TTN | c.18275C>A p.A6092D (on ENST00000591111; = p.A5165D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | PolyPhen benign (0.173); catalogued as COSV60301553; called by muse, mutect2, varscan2
- UPF3B | c.1009C>A p.P337T (on ENST00000276201 / NM_080632.3; = p.P324T on NM_023010.3) | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV52231379; called by muse, mutect2, varscan2
- USH2A | c.6235A>G p.K2079E | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as CM115974, COSV100230935, COSV56376400, COSV56425323; called by muse, mutect2, varscan2
- USP21 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as COSV57090967; called by muse, mutect2, varscan2
- USP29 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs1482296121, COSV54146183, COSV54147151; called by muse, mutect2, varscan2
- VSIG4 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV66074808; called by muse, mutect2, varscan2
- WAPL | c.2386A>T p.M796L | Missense Mutation (SNP) | VAF 54/59 reads (92%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53939587; called by muse, mutect2, varscan2
- WARS2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 64/156 reads (41%) | catalogued as COSV52482273; called by muse, mutect2, varscan2
- WDR44 | c.1913G>C p.R638T | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV54168188; called by muse, mutect2, varscan2
- WDR90 | c.4705G>T p.A1569S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.193); catalogued as rs759602844, COSV53474691, COSV99554066; called by muse, mutect2, varscan2
- XRCC4 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs747001193, COSV56544360; called by muse, mutect2, varscan2
- ZADH2 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs368098178; called by muse, mutect2, varscan2
- ZC3H3 | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV52794353; called by muse, mutect2, varscan2
- ZFHX4 | c.4265G>T p.R1422L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50479876, COSV51492245, COSV99262664; called by muse, mutect2, varscan2
- ZIC4 | c.853A>G p.M285V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1172936220, COSV67173887; called by muse, mutect2, varscan2
- ZNF215 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as rs761462750, COSV53492626, COSV53492833, COSV99549690; called by muse, mutect2, varscan2
- ZNF418 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV101268867; called by muse, mutect2, varscan2
- ZNF536 | c.3363G>T p.M1121I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV62833005; called by muse, mutect2, varscan2
- ZNF592 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV55439256; called by muse, mutect2, varscan2
- ZNF75D | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV66133394; called by muse, mutect2, varscan2
- ZNF99 | c.345A>T p.K115N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); catalogued as COSV68056554; called by muse, mutect2, varscan2
- BCHE | c.1799_1800del p.V600Gfs*37 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by pindel, varscan2
- CNBD1 | c.795del p.T266Lfs*18 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, pindel, varscan2
- COX8A | c.178_186del p.S60_L62del | In Frame Del (DEL) | VAF 54/128 reads (42%) | called by mutect2, pindel, varscan2
- DGKB | c.2287dup p.W763Lfs*53 (on ENST00000399322 / NM_001350722.2; = p.W763Lfs*26 on NM_145695.2) | Frame Shift Ins (INS) | VAF 63/165 reads (38%) | called by mutect2, pindel, varscan2
- DNAH8 | c.1252del p.R418Efs*10 | Frame Shift Del (DEL) | VAF 53/166 reads (32%) | called by mutect2, pindel, varscan2
- ERICH3 | c.2176+2del p.X726_splice | Splice Site (DEL) | VAF 141/421 reads (33%) | called by mutect2, pindel, varscan2
- GBA3 | c.798del p.V267Lfs*9 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.259C>G p.P87A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV3-16 | c.63T>G p.Y21* | Nonsense Mutation (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- SDCCAG8 | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SUPT20HL1 | c.2016G>T p.Q672H | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SUPT6H | c.3042del p.T1015Pfs*15 | Frame Shift Del (DEL) | VAF 34/85 reads (40%) | called by mutect2, pindel, varscan2
- TRAJ23 | c.45del p.E16Sfs*4 | Frame Shift Del (DEL) | VAF 29/51 reads (57%) | called by mutect2, pindel, varscan2
- ABCD1 | c.735C>T p.A245= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs781829562, COSV54387523; called by muse, mutect2, varscan2
- ACOT4 | c.879G>C p.V293= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV100412748; called by muse, mutect2, varscan2
- ACSM5 | c.1638A>G p.P546= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs112747866, COSV59374441; called by muse, mutect2, varscan2
- ADAM12 | c.1401G>T p.G467= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV64113845; called by muse, mutect2, varscan2
- ADAM18 | c.2187C>A p.S729= | Silent (SNP) | VAF 458/523 reads (88%) | catalogued as COSV55846650, COSV55854096; called by muse, mutect2, varscan2
- ADAM23 | c.2493C>A p.P831= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV52228168; called by muse, mutect2, varscan2
- ADGRB3 | c.4311A>G p.L1437= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs769906337, COSV53258236; called by muse, mutect2, varscan2
- ADM | c.138G>T p.L46= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99534065; called by muse, mutect2, varscan2
- ADM | c.139C>A p.R47= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV99534069; called by muse, mutect2, varscan2
- ARMC12 | c.567G>T p.R189= (on ENST00000373866 / NM_001286574.2; = p.R216= on NM_145028.5) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99849246; called by muse, mutect2, varscan2
- ATG4D | c.255G>T p.R85= | Silent (SNP) | VAF 33/47 reads (70%) | catalogued as COSV58763442; called by muse, mutect2, varscan2
- ATP2B3 | c.2712C>A p.P904= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV54859672; called by muse, mutect2, varscan2
- ATP8B4 | c.3175C>A p.R1059= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV52723130; called by muse, mutect2, varscan2
- ATP8B4 | c.3159A>T p.P1053= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV52723138; called by muse, mutect2, varscan2
- BCL9 | c.2295G>C p.V765= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV52349451; called by muse, mutect2, varscan2
- CATSPER4 | c.1095C>T p.P365= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV58794478; called by muse, mutect2, varscan2
- CD109 | c.4011G>T p.V1337= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV54656030; called by muse, mutect2, varscan2
- CD300LD | c.264C>T p.H88= | Silent (SNP) | VAF 77/177 reads (44%) | catalogued as rs755931050, COSV60084548; called by muse, mutect2, varscan2
- CENPT | c.777C>T p.P259= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV54651948; called by muse, mutect2, varscan2
- CEP89 | c.588A>G p.Q196= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV59867302; called by muse, mutect2, varscan2
- CNTN5 | c.1659G>A p.G553= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV54289527; called by muse, mutect2, varscan2
- COL9A1 | c.408C>G p.S136= | Silent (SNP) | VAF 117/251 reads (47%) | catalogued as COSV61837242; called by muse, mutect2, varscan2
- CRMP1 | c.1191G>A p.R397= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as rs1293879756, COSV61479145; called by muse, mutect2, varscan2
- CXorf38 | c.567G>C p.L189= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV59948155; called by muse, mutect2, varscan2
- ENGASE | c.1011G>T p.V337= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs781739164, COSV56137623; called by muse, mutect2, varscan2
- EXOSC9 | c.882A>T p.T294= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as rs370861791, COSV54667791; called by muse, mutect2, varscan2
- FAT3 | c.3096G>T p.V1032= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV53165389; called by muse, mutect2, varscan2
- FRG2C | c.141C>T p.A47= | Silent (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- GAB4 | c.42A>C p.P14= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV68755114; called by muse, varscan2
- GFRAL | c.414T>C p.C138= | Silent (SNP) | VAF 80/198 reads (40%) | catalogued as COSV61234868; called by muse, mutect2, varscan2
- GPKOW | c.933C>G p.A311= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV50245003; called by muse, mutect2, varscan2
- GPX5 | c.621C>T p.V207= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as rs1393756719, COSV69079811; called by muse, mutect2, varscan2
- GRIK1 | c.123G>T p.G41= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV58730282; called by muse, mutect2, varscan2
- GRIN2B | c.3087C>T p.S1029= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV74207525; called by muse, mutect2, varscan2
- HEG1 | c.768G>T p.S256= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV60765136; called by muse, mutect2, varscan2
- IRAK3 | c.1254C>T p.L418= | Silent (SNP) | VAF 57/117 reads (49%) | catalogued as COSV54165060; called by muse, mutect2, varscan2
- ITGAX | c.987G>A p.L329= | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as COSV51645751; called by muse, varscan2
- KIAA1109 | c.13839A>T p.S4613= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as COSV52689788; called by muse, mutect2, varscan2
- LRRIQ1 | c.1266A>T p.I422= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as COSV67837437; called by muse, mutect2, varscan2
- MAGEB16 | c.747C>A p.L249= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV67874481; called by mutect2, varscan2
- MATK | c.747C>A p.V249= (on ENST00000310132 / NM_139355.3; = p.V250= on NM_002378.4) | Silent (SNP) | VAF 19/25 reads (76%) | catalogued as COSV59556432; called by muse, mutect2, varscan2
- MMP16 | c.186G>A p.V62= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV54186046; called by muse, mutect2, varscan2
- MUC16 | c.31866A>G p.L10622= | Silent (SNP) | VAF 49/64 reads (77%) | catalogued as COSV67489316; called by muse, mutect2, varscan2
- NEFM | c.1971G>T p.P657= | Silent (SNP) | VAF 33/37 reads (89%) | catalogued as COSV55331778, COSV55334679, COSV55334892; called by muse, varscan2
- NLRP11 | c.1656T>C p.N552= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as COSV64088625; called by muse, mutect2, varscan2
- OR1N2 | c.648G>A p.L216= | Silent (SNP) | VAF 109/131 reads (83%) | catalogued as COSV65461118; called by muse, mutect2, varscan2
- OR2D3 | c.405C>A p.S135= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV58573834; called by muse, mutect2, varscan2
- OR2T2 | c.105C>A p.I35= | Silent (SNP) | VAF 26/254 reads (10%) | catalogued as rs528774471, COSV61618126, COSV61618913; called by muse, mutect2
- OR51F1 | c.714C>T p.A238= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as rs1209454361, COSV58580681; called by muse, mutect2, varscan2
- OTUD5 | c.1638G>T p.L546= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs138137225, COSV50238799; called by muse, mutect2, varscan2
- OXR1 | c.2205A>G p.P735= (on ENST00000442977 / NM_001198532.1; = p.P707= on NM_018002.3) | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as rs762230852, COSV99860638; called by muse, mutect2, varscan2
- PALLD | c.2946G>T p.G982= (on ENST00000505667 / NM_001166108.2; = p.G965= on NM_016081.4) | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV54992919; called by muse, mutect2, varscan2
- PCLO | c.10624C>A p.R3542= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs746260871, CM154563, COSV61661540; called by muse, mutect2, varscan2
- PIP4K2C | c.396C>T p.S132= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as rs773282154, COSV61606915; called by muse, mutect2, varscan2
- PREX1 | c.3813G>T p.R1271= | Silent (SNP) | VAF 78/149 reads (52%) | catalogued as COSV64256104; called by muse, mutect2, varscan2
- PRRC2B | c.4008A>G p.A1336= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV61942407; called by muse, mutect2, varscan2
- PTPRZ1 | c.4314C>A p.S1438= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV66444410; called by muse, mutect2, varscan2
- RAB33A | c.174G>T p.G58= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99924442; called by muse, mutect2, varscan2
- RSPO3 | c.91C>A p.R31= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs1259070401, COSV63151377, COSV63152837; called by muse, mutect2, varscan2
- RYR2 | c.822T>A p.L274= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as COSV63710103; called by muse, mutect2, varscan2
- SLC35E1 | c.1116C>T p.L372= | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as rs1476416151, COSV68736311, COSV68736523; called by muse, mutect2, varscan2
- SPTB | c.117C>A p.L39= | Silent (SNP) | VAF 45/55 reads (82%) | catalogued as COSV67634713; called by muse, mutect2, varscan2
- SYNDIG1L | c.393G>A p.Q131= | Silent (SNP) | VAF 83/97 reads (86%) | catalogued as COSV59048314; called by muse, mutect2, varscan2
- TFCP2L1 | c.717C>A p.A239= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as COSV55294760; called by muse, mutect2, varscan2
- TGM5 | c.15A>G p.L5= | Silent (SNP) | VAF 48/83 reads (58%) | catalogued as rs200656120, COSV55011938; called by muse, mutect2, varscan2
- TMEM266 | c.1185C>T p.T395= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV66381394; called by muse, mutect2, varscan2
- TRIM24 | c.438G>A p.K146= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV100631188, COSV58977420; called by muse, mutect2, varscan2
- TTN | c.31237C>A p.R10413= (on ENST00000591111; = p.R9486= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100604322, COSV59923102; called by muse, mutect2, varscan2
- VGLL1 | c.531C>T p.C177= | Silent (SNP) | VAF 7/152 reads (5%) | catalogued as COSV65703793; called by muse, mutect2
- VIM | c.552C>T p.R184= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs1284367198, COSV56407482; called by muse, mutect2, varscan2
- ZFHX4 | c.5238G>T p.T1746= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV50651121, COSV51492261; called by muse, mutect2, varscan2
- CTBP2 | c.58+11828G>A | Intron (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100455970; called by muse, mutect2, varscan2
- DTWD2 | c.218+13676A>T | Intron (SNP) | VAF 41/158 reads (26%) | called by muse, mutect2, varscan2
- FBLN1 | c.1698-9615G>T | Intron (SNP) | VAF 15/40 reads (38%) | catalogued as COSV53046799; called by muse, mutect2, varscan2
- IKBIP | c.297+8232A>G | Intron (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100141624; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866915 A>G | 5'Flank (SNP) | VAF 37/153 reads (24%) | called by muse, mutect2, varscan2
- ZNF214 | c.-1G>T | 5'UTR (SNP) | VAF 17/65 reads (26%) | catalogued as rs200417007, COSV99547036; called by muse, mutect2, varscan2
- ZNF322P1 | n.23G>A | RNA (SNP) | VAF 82/157 reads (52%) | called by muse, mutect2, varscan2
